Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7077, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7077-01A (Primary Tumor).

[page 1 of 2]
D.O.B.
SSN #
MRN #
Ref Physician

TCGA-HC-7077

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. Soft tissue, prostate/urinary bladder, posterior neck, excision:
No evidence of malignancy.

B. Soft tissue, prostate/urinary bladder, anterior neck, excision:
No evidence of malignancy.

C. Prostate, radical prostatectomy:

Adenocarcinoma

Tumor Characteristics:

1. Histologic type: **Adenocarcinoma**
2. Gleason's Grade:
- a. Primary pattern: 3 of 5.
- b. Secondary pattern: 3 of 5.
- c. Score: **6 of 10**
3. Tumor involves: **Both lobes**
4. Tumor quantitation: Approximately **25%**
5. Seminal vesicle involvement: Absent.
6. **Extracapsular tumor extension: Present** (block C8).
7. Lymphovascular space invasion: Absent.
8. **Perineural space invasion: Present**
9. High-grade PIN: Present.
Surgical Margin Status:
1. Bladder Neck: No evidence of malignancy.
2. Apical (Inferior): No evidence of malignancy.
3. Inked prostatic margin: No evidence of malignancy.Lymph Node Status: None resected.
Other significant findings:
1. Other findings: A small amount of tumor was noted on the right side (block C6). However, tumor cells were identified adjacent to adipose tissue constituting **unilateral extracapsular extension** (block C8). In other areas, prostatic hyperplasia was evident.
2. pTNM Stage: pT3a NX MX

Staging sheet # 34

Electronic Signature:

[page 2 of 2]
CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm prostate.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Posterior bladder neck.
- B. Anterior bladder neck.
- C. Prostate.

GROSS DESCRIPTION:

A. Received in a single container labeled . posterior bladder neck is a 1.6 x .7 x .6 cm. irregular firm tan-pink granular mass. Inked, trisected and entirely submitted in one cassette.

B. Received in a single container labeled ., anterior bladder neck is a .4 x .3 x .2 cm. granular tan-pink mass. Inked, bisected and entirely submitted in one cassette.

C. Received in a single container labeled . prostate is a 48 gram-radical prostatectomy, measuring 4.4 x 4.3 x 2.8 cm. The specimen is partially covered by a shaggy brown capsule. The specimen has been previously sectioned along the posterior aspect and sampled for research. The right side is inked black and the left side blue. The specimen is further sectioned to posterior to display a pale yellow poorly defined area of discoloration of the left lateral aspect of the distal level .05 cm in greatest dimension. Grossly it is 0.1 cm. from the inked posterior margin. The remainder of the cut surface is tan-yellow fibrous tissue. The seminal vesicles together measure 3.6 x 3.4 x .7 cm. Each has a tan-gray cystic cut surface and is grossly uninvolved by lesions grossly. Representative sections are submitted as follows:

Blocks 1 and 2—apical margin; 3—vesical margin; 4—distal left lateral; 5—distal right lateral; 6—distal right posterior; 7—distal left posterior; 8—left mid-lateral; 9—mid-right lateral; 10—mid-right posterior; 11—mid-left posterior; 12—proximal left lateral; 13—proximal right lateral; 14—proximal right posterior; 15—proximal left posterior; 16—origin of seminal vesicles; 17—representative left and right seminal vesicles. Two cassettes submitted for research

Source: NCI Genomic Data Commons file 9e387852-dc66-490f-88ae-a1fa2bbd960a (TCGA-HC-7077.67940700-DCD0-4E3C-9CCA-4F6DAEACF34C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).